Somatic mutation profile of tumor specimen TCGA-CV-A45R-01A (aliquot TCGA-CV-A45R-01A-11D-A24D-08) from TCGA case TCGA-CV-A45R, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage III; Tumor grade: G1; Age at diagnosis: 46.9 years (17,125 days).
Specimen TCGA-CV-A45R-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 022dec43-a1ee-41ca-afd6-310954a1494d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-A45R-10A (Blood Derived Normal), aliquot TCGA-CV-A45R-10A-01D-A24F-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cb552c1e-7b12-4c1a-8e8c-34ade163ac4d

The open-access MAF lists 92 somatic variants for this specimen: 69 protein-altering or splice-affecting, 23 silent.
By variant classification: Missense Mutation 61, Silent 23, Nonsense Mutation 6, Frame Shift Del 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1634A>G p.Y545C (on ENST00000281708 / NM_001349798.2; = p.Y465C on NM_018315.5) | Missense Mutation (SNP) | VAF 43/99 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1560758208, COSV55890892, COSV55908001, COSV55914345; called by muse, mutect2, varscan2
- PIK3CA | c.1637A>G p.Q546R | Missense Mutation (SNP) | VAF 17/37 reads (46%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.934); catalogued as rs397517201, COSV55875400, COSV55876869, COSV55877455; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.832C>T p.P278S | Missense Mutation (SNP) | VAF 30/49 reads (61%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as rs17849781, CM011015, CM052927, CM120850, CX0910928, COSV52668132, COSV52679740, COSV52684662, COSV52950563; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCC9 | c.740C>T p.A247V | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT tolerated (0.49); PolyPhen benign (0.009); catalogued as COSV99685623; called by muse, mutect2, varscan2
- ACSS3 | c.1031G>T p.W344L | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99698750; called by muse, mutect2, varscan2
- ACTN3 | c.2161G>A p.V721I | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT tolerated (0.09); PolyPhen benign (0.363); catalogued as rs557548998, COSV100074253; called by muse, mutect2, varscan2
- AGTR1 | c.658A>G p.K220E | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.733); catalogued as COSV100837030; called by muse, mutect2, varscan2
- ANO1 | c.221C>T p.S74L | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as rs1282388664, COSV60289166; called by muse, mutect2, varscan2
- AP1G1 | c.70C>T p.R24* | Nonsense Mutation (SNP) | VAF 15/87 reads (17%) | catalogued as COSV100250408; called by muse, mutect2, varscan2
- APBA2 | c.1793C>A p.A598D | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101258159; called by muse, mutect2, varscan2
- CHRNB3 | c.943G>A p.V315M | Missense Mutation (SNP) | VAF 27/262 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs532561485, COSV51499009; called by muse, mutect2
- CLCNKA | c.1267G>T p.A423S | Missense Mutation (SNP) | VAF 27/291 reads (9%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.971); catalogued as COSV100510073; called by muse, mutect2
- CNTN4 | c.778C>T p.R260* | Nonsense Mutation (SNP) | VAF 3/12 reads (25%) | catalogued as rs755471277, COSV61871857; called by muse, mutect2
- CNTNAP4 | c.3172G>C p.V1058L | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.029); catalogued as COSV100271272; called by muse, mutect2, varscan2
- DNAJC5 | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.055); catalogued as COSV100694222; called by muse, mutect2
- DPP10 | c.706C>G p.L236V | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100064571; called by muse, mutect2, varscan2
- EML5 | c.3739A>T p.T1247S | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT tolerated (0.91); PolyPhen benign (0.001); catalogued as COSV100715585; called by muse, mutect2, varscan2
- ENPEP | c.274C>T p.R92* | Nonsense Mutation (SNP) | VAF 14/113 reads (12%) | catalogued as rs143343563, COSV54448047; called by muse, mutect2, varscan2
- FAM3B | c.532G>T p.E178* | Nonsense Mutation (SNP) | VAF 9/43 reads (21%) | catalogued as COSV100783734; called by muse, mutect2, varscan2
- FAT1 | c.12847G>A p.E4283K | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs202133523, COSV71675044; called by muse, mutect2, varscan2
- FLVCR2 | c.581T>A p.I194N | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99471282; called by muse, mutect2, varscan2
- FRYL | c.7585G>A p.E2529K | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.021); catalogued as COSV99976837; called by muse, mutect2, varscan2
- GALR3 | c.734C>T p.A245V | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.55); catalogued as COSV99968032; called by muse, mutect2
- GEMIN5 | c.4031G>A p.R1344K | Missense Mutation (SNP) | VAF 43/138 reads (31%) | SIFT tolerated, low confidence (0.97); PolyPhen benign (0); catalogued as COSV99593860; called by muse, mutect2, varscan2
- GPR45 | c.668G>A p.R223H | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1256576888, COSV99306700; called by muse, mutect2, varscan2
- HTR1E | c.391G>A p.A131T | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.416); catalogued as rs764472292, COSV100541091, COSV59511258; called by muse, mutect2, varscan2
- KCNG4 | c.25G>A p.G9S | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.001); catalogued as COSV100377051; called by muse, mutect2, varscan2
- KCNJ4 | c.1178C>T p.A393V | Missense Mutation (SNP) | VAF 54/147 reads (37%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs753595753, COSV57856295; called by muse, mutect2, varscan2
- KIAA0232 | c.2318C>G p.T773S | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as rs747608911, COSV100300683; called by muse, mutect2, varscan2
- KIR2DL3 | c.524C>T p.P175L | Missense Mutation (SNP) | VAF 26/184 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.027); catalogued as COSV100667846; called by muse, mutect2, varscan2
- LDHAL6A | c.444G>C p.W148C | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99323924; called by muse, mutect2, varscan2
- LRRC42 | c.854G>A p.G285D | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.97); catalogued as COSV100066491; called by muse, mutect2, varscan2
- LRRC49 | c.1159G>C p.E387Q | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.78); catalogued as COSV99537453; called by muse, mutect2, varscan2
- MCM4 | c.2450C>T p.A817V | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as COSV100031528; called by muse, mutect2, varscan2
- MEF2A | c.362A>T p.D121V | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.51); catalogued as COSV100573726; called by muse, mutect2, varscan2
- METTL1 | c.694G>A p.G232R | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT tolerated (0.55); PolyPhen benign (0.005); catalogued as rs768855649, COSV99141561; called by muse, mutect2, varscan2
- MYF5 | c.608G>A p.S203N | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99953266; called by muse, mutect2, varscan2
- NFKB1 | c.700G>A p.V234M (on ENST00000394820 / NM_001382627.1; = p.V235M on NM_003998.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768698948, COSV99897137; called by muse, mutect2, varscan2
- NIPSNAP2 | c.137T>C p.L46P | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.903); catalogued as COSV100436704; called by muse, mutect2, varscan2
- OBSCN | c.12257G>A p.R4086Q | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.904); catalogued as rs368911997; called by muse, mutect2, varscan2
- OR10G7 | c.922G>T p.A308S | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100389916; called by muse, mutect2, varscan2
- P2RX3 | c.284A>G p.K95R | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.244); catalogued as COSV99628611; called by muse, mutect2, varscan2
- PAPPA | c.2831G>T p.S944I | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.475); catalogued as COSV100073997; called by muse, mutect2, varscan2
- PDZD9 | c.698C>T p.S233F (on ENST00000424898 / NM_001363519.1; = p.S173F on NM_173806.4) | Missense Mutation (SNP) | VAF 49/270 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV99193314; called by muse, mutect2, varscan2
- PHKG2 | c.434A>G p.H145R | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100079565; called by muse, mutect2, varscan2
- PLXNB2 | c.212C>T p.P71L | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1233673658, COSV63781813; called by muse, mutect2, varscan2
- PRMT1 | c.283G>A p.V95I | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.555); catalogued as COSV101212264; called by muse, mutect2, varscan2
- PROX1 | c.1240G>A p.D414N | Missense Mutation (SNP) | VAF 57/173 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as rs752227508, COSV54778926, COSV54779265; called by muse, mutect2, varscan2
- PSMD1 | c.1111A>G p.I371V | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0.109); catalogued as COSV100433569; called by muse, mutect2, varscan2
- RAD51C | c.251A>T p.K84M | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.726); catalogued as rs1372016419, COSV53622933, COSV99542177; called by muse, mutect2, varscan2
- RUNX1T1 | c.224C>T p.T75M (on ENST00000265814 / NM_001198628.1; = p.T48M on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as rs780681800, COSV99750032; called by muse, mutect2, varscan2
- SELENOO | c.1802C>T p.A601V | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.958); catalogued as rs761227143, COSV50538240; called by muse, mutect2, varscan2
- SEZ6L | c.451T>C p.S151P | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV99962012; called by muse, mutect2, varscan2
- SLC30A10 | c.1420C>G p.Q474E | Missense Mutation (SNP) | VAF 56/214 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.073); catalogued as COSV100751495; called by muse, mutect2, varscan2
- SPSB4 | c.472G>A p.G158S | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.38); PolyPhen benign (0.023); catalogued as COSV100141295; called by muse, mutect2
- STX1A | c.82C>T p.R28C | Missense Mutation (SNP) | VAF 52/163 reads (32%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.61); catalogued as rs782703876, COSV56109050; called by muse, mutect2, varscan2
- SUCO | c.2626C>G p.L876V | Missense Mutation (SNP) | VAF 45/137 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV99742739; called by muse, mutect2, varscan2
- SYNE1 | c.9484C>T p.H3162Y (on ENST00000367255 / NM_182961.4; = p.H3169Y on NM_033071.3) | Missense Mutation (SNP) | VAF 44/174 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.529); catalogued as rs1201355219, COSV99563174; called by muse, mutect2, varscan2
- TNRC18 | c.2201G>A p.R734Q | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.799); catalogued as rs770701991, COSV101269651; called by muse, mutect2, varscan2
- TRPV1 | c.748G>T p.E250* | Nonsense Mutation (SNP) | VAF 14/24 reads (58%) | catalogued as COSV99439512; called by muse, mutect2, varscan2
- WDFY3 | c.3731C>T p.T1244M | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.216); catalogued as rs755448011, COSV99883437; called by muse, mutect2, varscan2
- WNT9A | c.868G>A p.V290M | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.292); catalogued as rs759994026, COSV99688204; called by muse, varscan2
- WWP2 | c.1312C>T p.Q438* | Nonsense Mutation (SNP) | VAF 18/78 reads (23%) | catalogued as COSV100598539; called by muse, mutect2, varscan2
- ZDHHC14 | c.796G>A p.V266I | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.251); catalogued as rs537154606, COSV58194367; called by muse, mutect2, varscan2
- ZNF697 | c.104A>C p.E35A | Missense Mutation (SNP) | VAF 41/131 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV101360151; called by muse, mutect2, varscan2
- ZNF831 | c.2546A>G p.Q849R | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV100925999; called by muse, mutect2, varscan2
- CDKN2A | c.233_234del p.L78Hfs*41 | Frame Shift Del (DEL) | VAF 14/43 reads (33%) | called by pindel, varscan2
- NOTCH1 | c.455G>T p.G152V | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- ZKSCAN2 | c.1302_1313del p.T435_P438del | In Frame Del (DEL) | VAF 12/109 reads (11%) | called by mutect2, pindel
- ALDH3A1 | c.426G>A p.L142= | Silent (SNP) | VAF 15/93 reads (16%) | catalogued as COSV99855867; called by muse, mutect2, varscan2
- ARID1A | c.1869A>G p.G623= | Silent (SNP) | VAF 37/136 reads (27%) | catalogued as COSV100251593; called by muse, mutect2, varscan2
- ATRNL1 | c.2727C>T p.C909= | Silent (SNP) | VAF 14/70 reads (20%) | catalogued as COSV100370560; called by muse, mutect2, varscan2
- CNKSR1 | c.1050G>A p.L350= (on ENST00000374253 / NM_001297647.2; = p.L343= on NM_006314.3) | Silent (SNP) | VAF 16/38 reads (42%) | catalogued as COSV100836691; called by muse, mutect2
- COL21A1 | c.1527G>A p.G509= | Silent (SNP) | VAF 21/66 reads (32%) | catalogued as COSV99778617; called by muse, mutect2, varscan2
- DIP2A | c.2256C>T p.S752= | Silent (SNP) | VAF 9/61 reads (15%) | catalogued as COSV100595732; called by muse, mutect2, varscan2
- DNAH5 | c.12582T>C p.T4194= | Silent (SNP) | VAF 6/51 reads (12%) | catalogued as rs1428718985, COSV99449462; called by muse, mutect2, varscan2
- DPP9 | c.1353C>T p.F451= (on ENST00000598800; = p.F480= on NM_139159.5) | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as COSV99506091; called by muse, mutect2, varscan2
- DSCAM | c.5871G>A p.T1957= | Silent (SNP) | VAF 15/51 reads (29%) | catalogued as rs776580525, COSV101260039; called by muse, mutect2, varscan2
- DSG3 | c.2445C>A p.I815= | Silent (SNP) | VAF 29/75 reads (39%) | catalogued as COSV99934128; called by muse, mutect2, varscan2
- DZANK1 | c.147C>A p.G49= | Silent (SNP) | VAF 3/10 reads (30%) | catalogued as COSV99362401; called by muse, mutect2
- GARNL3 | c.84G>A p.S28= | Silent (SNP) | VAF 23/142 reads (16%) | catalogued as rs141855938; called by muse, mutect2, varscan2
- JUND | c.381G>A p.K127= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as COSV99417203; called by muse, mutect2, varscan2
- LEMD2 | c.1431G>A p.T477= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as rs578140878, COSV99540655; called by muse, mutect2, varscan2
- LRFN5 | c.1642C>T p.L548= | Silent (SNP) | VAF 35/117 reads (30%) | catalogued as COSV53255336, COSV99983736; called by muse, mutect2, varscan2
- PADI3 | c.1443C>G p.P481= | Silent (SNP) | VAF 16/138 reads (12%) | catalogued as COSV64933839; called by muse, mutect2, varscan2
- PTCHD1 | c.1743G>A p.G581= | Silent (SNP) | VAF 25/98 reads (26%) | catalogued as rs1179436250, COSV101037633; called by muse, mutect2, varscan2
- SCARF1 | c.1947G>A p.A649= | Silent (SNP) | VAF 7/57 reads (12%) | catalogued as rs756463060, COSV99557018; called by muse, mutect2, varscan2
- SFRP1 | c.663C>T p.G221= | Silent (SNP) | VAF 16/73 reads (22%) | catalogued as rs145952780; called by muse, mutect2, varscan2
- SLIT2 | c.825C>T p.A275= | Silent (SNP) | VAF 24/83 reads (29%) | catalogued as rs557268494, COSV56580284; called by muse, mutect2, varscan2
- SLITRK1 | c.1680G>A p.T560= | Silent (SNP) | VAF 19/38 reads (50%) | catalogued as COSV100999943; called by muse, mutect2, varscan2
- TRIM58 | c.78G>A p.P26= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as rs966295016, COSV100825071, COSV100825380; called by muse, mutect2, varscan2
- XPO6 | c.1521C>T p.H507= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as rs201774423; called by muse, mutect2, varscan2
